Gene-level copy-number profile of tumor specimen C3N-00729-02 (profiled together with C3N-00729-03) from CPTAC case C3N-00729, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IB; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 86.3 years (31,527 days).
Specimen C3N-00729-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 593eb1e0-4536-4f64-ad60-7b7efdb19313.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00729-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/e1cadb6d-2294-4dc5-b755-c55df1e2a927

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 1,776; copy number 3: 205; copy number 4: 49,059; copy number 5: 521; copy number 6: 6,306; copy number 7: 70; copy number 8: 303; copy number 9: 28; copy number 10: 119; copy number 12: 10.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 157 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,331,657–202,592,706, 7 genes, copy number 9 (within-gene range 6–9): UBE2T, PPP1R12B, CYCSP4, RNU6-89P, AC099336.1, AC099336.2, SNORA70.
- chr3:168,858,659–168,928,598, 4 genes, copy number 9: RPL21P43, LINC02082, AC092954.1, AC092954.2.
- chr3:178,960,121–179,604,649, 19 genes, copy number 10: ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47.
- chr9:131,258,076–131,740,074, 10 genes, copy number 12 (within-gene range 6–12): FAM78A, PLPP7, PRRC2B, SNORD62A, SNORD62B, AL358781.1, POMT1, AL358781.2, UCK1, RAPGEF1.
- chr9:136,375,577–136,993,984, 55 genes, copy number 10: SNAPC4, ENTR1, PMPCA, INPP5E, SEC16A, C9orf163, NOTCH1, MIR4673, AL592301.1, MIR4674, NALT1, LINC01451, AL590226.1, EGFL7, MIR126, AGPAT2, DIPK1B, SNHG7, SNORA17B, SNORA17B, SNORA17A, AL355987.6, AL355987.5, LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3, CCDC183, AL355987.4, AL355987.2, CCDC183-AS1, RABL6, NCLP1, MIR4292, AJM1, PHPT1, MAMDC4, EDF1, TRAF2, MIR4479, AL807752.1, AL807752.5, FBXW5, C8G, LCN12, LINC02692, PTGDS, AL807752.7, LCNL1, PAXX.
- chr10:121,133,090–121,739,730, 7 genes, copy number 9: RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1.
- chr17:81,637,171–82,057,470, 45 genes, copy number 10 (within-gene range 6–10): TSPAN10, PDE6G, OXLD1, CCDC137, ARL16, HGS, MIR6786, AC139530.3, AC139530.1, MRPL12, AC139530.2, SLC25A10, GCGR, MCRIP1, PPP1R27, P4HB, AC145207.3, AC145207.9, AC145207.2, ARHGDIA, AC145207.5, AC145207.6, ALYREF, ANAPC11, NPB, PCYT2, SIRT7, MAFG, AC145207.8, MAFG-DT, PYCR1, AC145207.4, MYADML2, AC145207.1, NOTUM, AC145207.7, ASPSCR1, CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1.
- chr20:53,544,615–54,070,594, 10 genes, copy number 9: Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
